Somatic mutation profile of tumor specimen C3N-03051-02 (aliquot CPT0208770006) from CPTAC case C3N-03051, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.8 years (24,037 days).
Specimen C3N-03051-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b50692aa-86ef-4035-a5b6-ab99e9816c5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03051-31 (Blood Derived Normal), aliquot CPT0208820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6c21306-4d78-4dee-8cc0-fe2fa89ef6ed

The open-access MAF lists 428 somatic variants for this specimen: 286 protein-altering or splice-affecting, 74 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 74, Intron 27, RNA 21, Nonsense Mutation 20, Frame Shift Del 12, Splice Site 12, 3'UTR 8, Splice Region 7, 5'UTR 7, Frame Shift Ins 3, In Frame Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 23/211 reads (11%) | hotspot (GDC flag); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 48/198 reads (24%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 129/375 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs387906687, CM102582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 161/411 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.12110C>A p.A4037D | Missense Mutation (SNP) | VAF 82/413 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs768261653; called by muse, mutect2, varscan2
- ADCK1 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs140287525; called by muse, mutect2
- ADGRV1 | c.7300G>A p.E2434K | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV67991238; called by muse, mutect2, varscan2
- ADPRM | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs191283617; called by muse, mutect2, varscan2
- AGMO | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs111502804; called by muse, mutect2, varscan2
- AMOT | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV59066512; called by muse, mutect2, varscan2
- APPL1 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1453011600; called by muse, mutect2, varscan2
- ASB15 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs538574876; called by muse, mutect2, varscan2
- AXIN1 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.36); catalogued as rs764818271, COSV51987058; called by muse, mutect2, varscan2
- BAIAP3 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs555278409; called by muse, mutect2, varscan2
- BCAN | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148799690; called by muse, mutect2, varscan2
- BPIFC | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as COSV55912956; called by muse, mutect2, varscan2
- C3 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748352684, COSV55577398; called by muse, mutect2, varscan2
- C9orf131 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs766111399; called by muse, mutect2, varscan2
- CDH22 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1368682209; called by muse, varscan2
- CDH22 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1234541921; called by muse, varscan2
- CDKN2A | c.365del p.G122Afs*24 | Frame Shift Del (DEL) | VAF 241/805 reads (30%) | catalogued as CD1414342, CM001960, COSV58689831, COSV58700502; called by mutect2, pindel, varscan2
- CDYL2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763202229, COSV101629622; called by muse, mutect2, varscan2
- CEP135 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.173); catalogued as COSV99954752; called by muse, mutect2, varscan2
- CFTR | c.2845C>A p.H949N | Missense Mutation (SNP) | VAF 113/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940266; called by muse, mutect2, varscan2
- CGB5 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 83/703 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV56823406; called by muse, mutect2, varscan2
- CLCA1 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV52329290; called by muse, mutect2, varscan2
- CLVS1 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57976216; called by muse, mutect2, varscan2
- COL6A3 | c.5218G>A p.D1740N | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV55088631; called by muse, mutect2, varscan2
- CSMD3 | c.5093G>T p.R1698L (on ENST00000297405 / NM_001363185.1; = p.R1594L on NM_052900.3) | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145853495, COSV52121644; called by muse, mutect2, varscan2
- CSMD3 | c.2617A>T p.I873F (on ENST00000297405 / NM_001363185.1; = p.I769F on NM_052900.3) | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351879185; called by muse, mutect2, varscan2
- CUX2 | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1345506674; called by muse, mutect2, varscan2
- CYP11B2 | c.1206G>C p.L402F | Missense Mutation (SNP) | VAF 204/1251 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV100010603; called by muse, mutect2, varscan2
- DCDC1 | c.4529G>A p.R1510K (on ENST00000597505 / NM_001367979.1; = p.R617K on NM_020869.3) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100337864; called by muse, mutect2
- DGKQ | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs147014854, COSV56616367; called by muse, mutect2, varscan2
- DIAPH3 | c.3229G>T p.D1077Y (on ENST00000400324 / NM_001042517.2; = p.D814Y on NM_030932.3) | Missense Mutation (SNP) | VAF 160/440 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57369384, COSV57370396; called by muse, mutect2, varscan2
- DLGAP3 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.138); catalogued as rs370934625; called by muse, mutect2, varscan2
- DNM2 | c.1610G>A p.G537D (on ENST00000355667 / NM_001005360.3; = p.G533D on NM_004945.3) | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV58971972; called by muse, mutect2, varscan2
- EXOC3 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 75/434 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs1214295341; called by muse, mutect2, varscan2
- FNDC1 | c.1724C>A p.S575* | Nonsense Mutation (SNP) | VAF 79/145 reads (54%) | catalogued as rs772744362; called by muse, mutect2, varscan2
- FRMPD1 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 102/248 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs559954392, COSV100899619; called by muse, mutect2, varscan2
- FXR2 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV51468857; called by mutect2, varscan2
- GABRG1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1330643076, COSV54954998, COSV99778580; called by muse, mutect2, varscan2
- GOLGA6L22 | c.134C>A p.T45N | Missense Mutation (SNP) | VAF 100/652 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV57033096; called by muse, mutect2, varscan2
- GPC5 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs750580579; called by muse, mutect2, varscan2
- GPRIN3 | c.921T>G p.S307R | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs778586785, COSV60885590; called by muse, mutect2, varscan2
- GRAMD1B | c.733A>G p.M245V | Missense Mutation (SNP) | VAF 106/295 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs752857335; called by muse, mutect2, varscan2
- GUCY2C | c.2558A>G p.Y853C | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53792818; called by muse, mutect2, varscan2
- GULP1 | c.388A>C p.S130R | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100771029; called by muse, mutect2, varscan2
- GZMA | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV99956620; called by muse, mutect2, varscan2
- HCN1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 72/668 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1252720341; ClinVar: uncertain significance; called by muse, varscan2
- HIPK4 | c.1322T>A p.L441Q | Missense Mutation (SNP) | VAF 174/711 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.916); catalogued as rs1347126238; called by muse, mutect2, varscan2
- HORMAD2 | c.398T>C p.M133T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1234284195; called by muse, mutect2, varscan2
- HSD17B4 | c.1703G>T p.R568L (on ENST00000414835 / NM_001199291.3; = p.R543L on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as CM140813; called by muse, mutect2, varscan2
- HSPG2 | c.3398G>T p.R1133L | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780698968; called by muse, mutect2, varscan2
- IGFBP3 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 178/483 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs867623388; called by muse, mutect2, varscan2
- IGHD4-23 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 128/501 reads (26%) | catalogued as rs544463016; called by muse, mutect2, varscan2
- IGSF10 | c.7810A>G p.K2604E | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770497448; called by muse, mutect2, varscan2
- KCNMA1 | c.2714C>A p.T905K (on ENST00000286628 / NM_001161352.2; = p.T847K on NM_002247.4) | Missense Mutation (SNP) | VAF 99/406 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV54251924, COSV54268594; called by muse, mutect2, varscan2
- KMT2C | c.387C>T p.I129= | Splice Region (SNP) | VAF 8/88 reads (9%) | catalogued as rs766252143, COSV100068520; called by muse, mutect2
- KRT74 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 117/809 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.304); catalogued as rs1189151933; called by muse, mutect2, varscan2
- LIN28A | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1219153789; called by muse, mutect2, varscan2
- LRCH3 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1278141413, COSV58392614; called by muse, mutect2
- MAML2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 111/591 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1226491746; called by muse, mutect2, varscan2
- MEX3B | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61664177; called by muse, mutect2, varscan2
- MGP | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs910721901; called by muse, mutect2
- MINDY3 | c.840G>T p.W280C | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53219511; called by muse, mutect2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2, varscan2
- MRGPRX3 | c.411C>A p.Y137* | Nonsense Mutation (SNP) | VAF 99/436 reads (23%) | catalogued as rs141540513; called by muse, mutect2, varscan2
- MTHFR | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100928244; called by muse, mutect2
- MYBPC3 | c.1456T>C p.W486R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs397515902, CM1110693, COSV57024720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH13 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52836475; called by muse, mutect2, varscan2
- NAALADL2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 77/107 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs893661535, COSV69159054; called by muse, mutect2, varscan2
- NCR1 | c.865A>G p.R289G | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV99401133; called by muse, mutect2, varscan2
- NEUROD4 | c.698del p.G233Efs*25 | Frame Shift Del (DEL) | VAF 74/360 reads (21%) | catalogued as COSV54472414; called by mutect2, pindel, varscan2
- NLRP2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV54755462; called by muse, mutect2, varscan2
- OR10S1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs535482570, COSV101602493; called by muse, mutect2, varscan2
- OR2A25 | c.828T>A p.F276L | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV68716873; called by muse, mutect2, varscan2
- OR2W3 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100831684; called by muse, mutect2, varscan2
- OR4N5 | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV61320747, COSV99048812; called by muse, mutect2
- OR51G2 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 52/144 reads (36%) | catalogued as COSV58991649, COSV58993643; called by muse, mutect2, varscan2
- OR52K2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs766771557; called by muse, mutect2, varscan2
- OR5T2 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57588127; called by muse, mutect2, varscan2
- OR9Q2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs753139796; called by muse, mutect2, varscan2
- PCDH15 | c.1391C>A p.T464N | Missense Mutation (SNP) | VAF 88/348 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs768256726; called by muse, mutect2, varscan2
- PCDH19 | c.2904C>A p.D968E (on ENST00000373034 / NM_001184880.2; = p.D920E on NM_020766.3) | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55264658; called by muse, mutect2, varscan2
- PDPR | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 71/572 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV55349847; called by muse, mutect2, varscan2
- PEAK1 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759331417, COSV56934716; called by muse, mutect2, varscan2
- PGGHG | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs369157724; called by muse, mutect2, varscan2
- PPP1R16B | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV55375898; called by muse, mutect2
- PRDM9 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 53/621 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV57002265; called by muse, mutect2
- PSKH2 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 108/443 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs778160358; called by muse, mutect2, varscan2
- PUS1 | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 67/491 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1450176768; called by muse, mutect2, varscan2
- RAG1 | c.1490G>C p.R497T | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV55024838; called by muse, mutect2, varscan2
- RIMKLB | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.441); catalogued as rs773288313; called by mutect2, varscan2
- RIMS2 | c.2741G>T p.R914L (on ENST00000666250 / NM_001348490.2; = p.R722L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51659837, COSV99180011; called by muse, mutect2, varscan2
- RNF220 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as rs145054751; called by muse, mutect2, varscan2
- RYR1 | c.13345G>A p.E4449K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs531290623, COSV62090259; called by muse, mutect2
- SCN4A | c.4930G>C p.V1644L | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs775486265, COSV71125648; called by muse, mutect2, varscan2
- SGCD | c.551C>A p.A184E (on ENST00000435422 / NM_001128209.2; = p.A185E on NM_000337.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61912988; called by muse, mutect2, varscan2
- SLC6A3 | c.1644C>A p.Y548* | Nonsense Mutation (SNP) | VAF 100/543 reads (18%) | catalogued as COSV99547652; called by muse, mutect2, varscan2
- SLC7A3 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs971922392, COSV53227379; called by muse, mutect2, varscan2
- SLITRK2 | c.2424G>T p.R808S | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59426274; called by muse, mutect2, varscan2
- SORL1 | c.5059A>G p.I1687V | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs777019417; called by muse, mutect2, varscan2
- SYCP1 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV65695316; called by muse, mutect2, varscan2
- TEX35 | c.160-2A>T p.X54_splice | Splice Site (SNP) | VAF 20/53 reads (38%) | catalogued as COSV99273893; called by muse, mutect2, varscan2
- TNR | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1158312570, COSV54881700; called by muse, mutect2, varscan2
- TNRC18 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 532/1238 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101259469; called by muse, mutect2, varscan2
- TPST2 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV58678584; called by muse, mutect2, varscan2
- VIPR1 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs765605332, COSV57297316; called by muse, mutect2, varscan2
- VSIG4 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.161); catalogued as COSV66073820; called by muse, mutect2, varscan2
- WDR72 | c.2854T>A p.Y952N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV100854858; called by muse, mutect2, varscan2
- ZEB1 | c.2690G>T p.R897L | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV58054541; called by muse, mutect2, varscan2
- ZFP37 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65288710; called by muse, mutect2, varscan2
- ZNF219 | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV53882273; called by muse, mutect2, varscan2
- ZNF320 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV67088905; called by muse, mutect2, varscan2
- ZNF407 | c.5098G>C p.A1700P | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100225098; called by muse, mutect2
- ZNF492 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs367614371; called by muse, mutect2, varscan2
- ZNF569 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs751089348, COSV57599376; called by muse, mutect2, varscan2
- ZNF569 | c.-41C>G | Splice Region (SNP) | VAF 14/69 reads (20%) | catalogued as rs757520077; called by muse, mutect2, varscan2
- ZNF808 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); catalogued as COSV63121265; called by muse, mutect2, varscan2
- ABCC12 | c.3981G>A p.M1327I | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ABCC4 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAMTS2 | c.2385G>T p.W795C | Missense Mutation (SNP) | VAF 163/485 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS20 | c.178C>G p.H60D | Missense Mutation (SNP) | VAF 135/393 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- AK7 | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 58/500 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AMPH | c.1555G>T p.G519C | Missense Mutation (SNP) | VAF 64/572 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ANKRD30B | c.2131+2T>A p.X711_splice | Splice Site (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.4171C>G p.R1391G (on ENST00000310343 / NM_001378025.1; = p.R1042G on NM_014715.4) | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- ARHGAP32 | c.4162_4168del p.D1388Pfs*29 (on ENST00000310343 / NM_001378025.1; = p.D1039Pfs*29 on NM_014715.4) | Frame Shift Del (DEL) | VAF 98/353 reads (28%) | called by mutect2, pindel, varscan2
- ARHGEF25 | c.666G>T p.L222F | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ARID1A | c.5952_5953del p.S1985Qfs*13 | Frame Shift Del (DEL) | VAF 60/448 reads (13%) | called by pindel, varscan2
- ARIH1 | c.267_269del p.G90del | In Frame Del (DEL) | VAF 37/148 reads (25%) | called by pindel, varscan2
- ATXN7L1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEGAIN | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRDT | c.1956T>A p.S652R | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C3orf56 | c.188C>A p.S63Y | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- C8orf76 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 55/410 reads (13%) | called by muse, mutect2, varscan2
- CBX6 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CCDC141 | c.550del p.L184Ffs*2 | Frame Shift Del (DEL) | VAF 29/144 reads (20%) | called by mutect2, pindel
- CDC42EP5 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 95/403 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.6082-1G>T p.X2028_splice | Splice Site (SNP) | VAF 61/174 reads (35%) | called by muse, mutect2, varscan2
- CLASP1 | c.3830A>G p.D1277G | Missense Mutation (SNP) | VAF 76/482 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CNOT1 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 39/390 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL14A1 | c.1967T>C p.L656S | Missense Mutation (SNP) | VAF 118/248 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL4A6 | c.2912A>C p.K971T | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CRYBB3 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CSMD2 | c.8313G>A p.L2771= | Splice Region (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- CTSA | c.603del p.X201_splice | Splice Site (DEL) | VAF 172/668 reads (26%) | called by mutect2, pindel, varscan2
- DCAF12L2 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DHX30 | c.305A>G p.Y102C (on ENST00000445061 / NM_138615.3; = p.Y63C on NM_014966.3) | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DIO1 | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLG3 | c.1005C>A p.D335E | Missense Mutation (SNP) | VAF 85/198 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DLGAP1 | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- DMRTA2 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 74/372 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH17 | c.13363G>A p.A4455T | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DNAH6 | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.024); called by muse, mutect2
- DNAJA2 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DPYD | c.1950G>A p.W650* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- DUSP8 | c.819C>G p.Y273* | Nonsense Mutation (SNP) | VAF 96/249 reads (39%) | called by muse, mutect2, varscan2
- E2F7 | c.1896T>G p.D632E | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- EDIL3 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFCC1 | c.1660+1G>T p.X554_splice | Splice Site (SNP) | VAF 109/270 reads (40%) | called by muse, mutect2, varscan2
- EIF4G1 | c.3940C>T p.Q1314* (on ENST00000346169 / NM_198241.3; = p.Q1119* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 58/904 reads (6%) | called by muse, mutect2
- EP400 | c.4639G>T p.A1547S | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FAM135B | c.1725G>T p.Q575H | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT1 | c.9506_9508del p.D3169del | In Frame Del (DEL) | VAF 28/116 reads (24%) | called by mutect2, pindel, varscan2
- FOXH1 | c.280-2A>G p.X94_splice | Splice Site (SNP) | VAF 361/762 reads (47%) | called by muse, mutect2, varscan2
- GBE1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- GRINA | c.175del p.H59Mfs*109 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- GYPC | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 138/482 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HERC1 | c.7007G>A p.G2336E | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HLA-E | c.100T>G p.S34A | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- HSP90AA1 | c.163-4A>C | Splice Region (SNP) | VAF 65/252 reads (26%) | called by muse, mutect2, varscan2
- HTR7 | c.1127del p.N376Tfs*16 | Frame Shift Del (DEL) | VAF 48/216 reads (22%) | called by mutect2, pindel, varscan2
- IL17C | c.105C>A p.H35Q | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2
- IRAG1 | c.1612G>C p.V538L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- JAKMIP1 | c.1243-2A>G p.X415_splice | Splice Site (SNP) | VAF 78/227 reads (34%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD4 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, varscan2
- KIAA1109 | c.3743G>A p.G1248D | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- KIF25 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLKB1 | c.409T>C p.C137R | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- KMT2C | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, varscan2
- KMT2C | c.1958T>C p.I653T | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, varscan2
- LIPI | c.332C>A p.P111Q | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAN2B1 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 71/567 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAPRE2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 37/239 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MARCHF1 | c.445A>G p.T149A (on ENST00000274056; = p.T132A on NM_017923.4) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MC2R | c.696G>T p.W232C | Missense Mutation (SNP) | VAF 129/485 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED17 | c.352A>G p.I118V | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MESP1 | c.275A>T p.K92I | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMEL1 | c.2326T>C p.C776R | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC12 | c.16300T>A p.W5434R (on ENST00000379442; = p.W5291R on NM_001164462.1) | Missense Mutation (SNP) | VAF 112/383 reads (29%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYO5C | c.4835A>T p.Y1612F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- NDE1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NDUFS7 | c.53+1G>A p.X18_splice | Splice Site (SNP) | VAF 83/547 reads (15%) | called by muse, mutect2, varscan2
- NLRP11 | c.1283C>A p.S428Y | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NR0B1 | c.995A>T p.E332V | Missense Mutation (SNP) | VAF 188/397 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NRBP1 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NSUN2 | c.1487G>T p.S496I | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NYAP1 | c.2009A>G p.E670G | Missense Mutation (SNP) | VAF 181/516 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10K2 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- OR7C2 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8G1 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- OR9G1 | c.102C>A p.Y34* | Nonsense Mutation (SNP) | VAF 87/698 reads (12%) | called by muse, mutect2, varscan2
- PAF1 | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 58/554 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PAF1 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCK1 | c.443del p.P148Rfs*13 | Frame Shift Del (DEL) | VAF 143/618 reads (23%) | called by mutect2, pindel, varscan2
- PDZD3 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 56/396 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIGQ | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3CA | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- PLCH1 | c.656T>G p.L219W (on ENST00000340059 / NM_001130960.2; = p.L231W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PNMT | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 68/347 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PNPLA8 | c.911G>C p.G304A | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PNPT1 | c.1883T>A p.L628* | Nonsense Mutation (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- PPM1M | c.505dup p.L169Pfs*48 (on ENST00000296487; = p.L330Pfs*48 on NM_144641.4) | Frame Shift Ins (INS) | VAF 67/201 reads (33%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PRAME | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 111/449 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PSMD13 | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2 | c.867+2T>C p.X289_splice | Splice Site (SNP) | VAF 181/366 reads (49%) | called by muse, mutect2, varscan2
- RABGAP1L | c.1115dup p.N372Kfs*9 | Frame Shift Ins (INS) | VAF 36/149 reads (24%) | called by mutect2, pindel, varscan2
- RIPK2 | c.894A>T p.E298D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROMO1 | c.129C>G p.L43= | Splice Region (SNP) | VAF 11/291 reads (4%) | called by muse, mutect2
- SAXO1 | c.789del p.L264* | Frame Shift Del (DEL) | VAF 75/321 reads (23%) | called by mutect2, pindel, varscan2
- SBK2 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- SCNN1G | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 153/525 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SF3B2 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- SFMBT2 | c.1559-2A>G p.X520_splice | Splice Site (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- SHANK3 | c.1479G>T p.V493= | Splice Region (SNP) | VAF 111/497 reads (22%) | called by muse, mutect2, varscan2
- SHANK3 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 115/493 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- SIRPB1 | c.851T>A p.L284Q | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC2A9 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 108/320 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SLC35F1 | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SLC7A14 | c.1346C>A p.T449N | Missense Mutation (SNP) | VAF 200/573 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO1A2 | c.544T>A p.Y182N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK4 | c.1547T>C p.V516A | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SRC | c.140A>T p.H47L | Missense Mutation (SNP) | VAF 124/589 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SRPX | c.621A>C p.E207D | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SS18L1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 59/425 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ST18 | c.767G>T p.R256M | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STRN3 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SVIL | c.3419A>C p.E1140A (on ENST00000355867 / NM_021738.3; = p.E714A on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- SYCP1 | c.1604G>T p.S535I | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SYNE3 | c.2221A>G p.R741G | Missense Mutation (SNP) | VAF 161/763 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SYT13 | c.753_767del p.H252_G256del | In Frame Del (DEL) | VAF 63/290 reads (22%) | called by mutect2, pindel, varscan2
- TACR1 | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TAS2R20 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- TBC1D12 | c.1499A>G p.N500S | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TBX21 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.433); called by mutect2, varscan2
- TBX21 | c.240_241insT p.P81Sfs*43 | Frame Shift Ins (INS) | VAF 45/222 reads (20%) | called by mutect2, pindel*, varscan2
- TDRD15 | c.3772G>T p.V1258F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TESC | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TET3 | c.2667del p.I890Lfs*5 | Frame Shift Del (DEL) | VAF 23/201 reads (11%) | called by mutect2, pindel, varscan2
- TEX37 | c.510C>A p.N170K | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TMEM26 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM30B | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 90/634 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TRAV12-2 | c.187A>T p.K63* | Nonsense Mutation (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- TRIM49 | c.466A>T p.R156* | Nonsense Mutation (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- TRPC5 | c.58del p.L20Cfs*4 | Frame Shift Del (DEL) | VAF 55/136 reads (40%) | called by mutect2, pindel, varscan2
- TTN | c.76720G>A p.G25574S (on ENST00000591111; = p.G18150S on NM_003319.4) | Missense Mutation (SNP) | VAF 43/136 reads (32%) | PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TTN | c.31049C>A p.P10350Q (on ENST00000591111; = p.P9423Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TUSC1 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 217/696 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- TXNRD3 | c.1409T>C p.V470A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TYK2 | c.1403A>G p.D468G | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- UNC45B | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- USP13 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- USP13 | c.1710-1G>T p.X570_splice | Splice Site (SNP) | VAF 30/103 reads (29%) | called by muse, mutect2, varscan2
- USP48 | c.1964-7A>T | Splice Region (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2
- VSTM2B | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 119/1008 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWA3A | c.2384-1G>T p.X795_splice | Splice Site (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- VWA5B1 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 85/464 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- VWC2L | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- XRN2 | c.1703A>G p.Y568C | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H12B | c.1534A>C p.S512R | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.7111G>T p.D2371Y | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZFP30 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 21/306 reads (7%) | called by muse, mutect2
- ZNF334 | c.1116_1117del p.G373Rfs*5 | Frame Shift Del (DEL) | VAF 22/232 reads (9%) | called by pindel, varscan2
- ZNF541 | c.3688G>T p.E1230* | Nonsense Mutation (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- ZNF606 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 69/469 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ZNF721 | c.1649G>T p.C550F (on ENST00000338977; = p.C562F on NM_133474.4) | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF841 | c.2167C>T p.H723Y (on ENST00000426391 / NM_001369830.1; = p.H839Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF845 | c.1118A>G p.H373R | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF853 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ZSCAN18 | c.1444C>G p.R482G | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.048); called by muse, varscan2
- ABCG4 | c.855C>A p.V285= | Silent (SNP) | VAF 39/315 reads (12%) | called by muse, mutect2, varscan2
- ABLIM1 | c.1308A>G p.A436= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as rs776291606; called by muse, mutect2, varscan2
- ACAA2 | c.450A>G p.V150= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs747244408; called by muse, mutect2, varscan2
- ADCY2 | c.2259G>T p.V753= | Silent (SNP) | VAF 62/336 reads (18%) | catalogued as COSV57876004; called by muse, mutect2, varscan2
- AHCYL2 | c.1188A>G p.V396= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- ALS2CL | c.2848A>C p.R950= | Silent (SNP) | VAF 68/221 reads (31%) | called by muse, mutect2, varscan2
- ANKRD24 | c.3396C>T p.L1132= | Silent (SNP) | VAF 52/496 reads (10%) | catalogued as COSV53670572; called by muse, mutect2, varscan2
- ARHGAP42 | c.897A>T p.T299= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- BEND3 | c.882G>A p.A294= | Silent (SNP) | VAF 53/397 reads (13%) | catalogued as rs145453246; called by muse, mutect2, varscan2
- C3orf56 | c.189C>A p.S63= | Silent (SNP) | VAF 94/379 reads (25%) | called by muse, mutect2, varscan2
- CACNA1E | c.3171G>T p.T1057= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as rs537667743, COSV100705803; called by muse, mutect2, varscan2
- CAGE1 | c.1272C>T p.Y424= (on ENST00000512086; = p.Y288= on NM_205864.3) | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- CAMLG | c.228C>T p.L76= | Silent (SNP) | VAF 43/236 reads (18%) | catalogued as rs987834942; called by muse, mutect2, varscan2
- CCDC144A | c.2712G>A p.Q904= | Silent (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- CCDC178 | c.381T>C p.T127= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100284911; called by mutect2, varscan2
- CCDC7 | c.378G>T p.G126= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- CDH8 | c.1782C>A p.I594= | Silent (SNP) | VAF 82/614 reads (13%) | called by muse, mutect2, varscan2
- CFAP65 | c.3783C>T p.H1261= | Silent (SNP) | VAF 63/397 reads (16%) | catalogued as rs756855581; called by muse, mutect2, varscan2
- CLCN3 | c.2193G>T p.R731= | Silent (SNP) | VAF 128/392 reads (33%) | catalogued as rs780341138; called by muse, mutect2, varscan2
- CLVS1 | c.837C>T p.D279= | Silent (SNP) | VAF 69/324 reads (21%) | catalogued as rs1223856004; called by muse, mutect2, varscan2
- CROCC | c.2490C>T p.S830= | Silent (SNP) | VAF 32/307 reads (10%) | catalogued as rs1282147566; called by muse, mutect2, varscan2
- CSMD3 | c.5265G>A p.L1755= (on ENST00000297405 / NM_001363185.1; = p.L1651= on NM_052900.3) | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV52340762; called by muse, mutect2, varscan2
- CUEDC1 | c.39C>G p.G13= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, varscan2
- DCLK3 | c.1557C>T p.Y519= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as rs778712003, COSV69362566; called by muse, mutect2, varscan2
- DNAJC10 | c.1890A>G p.R630= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- DUSP2 | c.360G>T p.A120= | Silent (SNP) | VAF 120/434 reads (28%) | called by muse, mutect2, varscan2
- EXOC3L4 | c.1251C>G p.L417= | Silent (SNP) | VAF 55/251 reads (22%) | called by muse, mutect2, varscan2
- FAM171B | c.1935A>C p.P645= | Silent (SNP) | VAF 84/256 reads (33%) | called by muse, mutect2, varscan2
- FSHR | c.1191C>A p.P397= | Silent (SNP) | VAF 62/483 reads (13%) | called by muse, mutect2, varscan2
- HMCN2 | c.11247G>A p.Q3749= | Silent (SNP) | VAF 114/318 reads (36%) | catalogued as rs919558182; called by muse, mutect2, varscan2
- HSPA12B | c.1350T>C p.C450= | Silent (SNP) | VAF 119/475 reads (25%) | catalogued as rs1199154582; called by muse, mutect2, varscan2
- INCENP | c.9G>A p.T3= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs750181207; called by muse, mutect2, varscan2
- INMT | c.645C>T p.A215= | Silent (SNP) | VAF 245/679 reads (36%) | catalogued as rs1342594078, COSV50003288; called by muse, mutect2, varscan2
- ITGAD | c.1761G>T p.L587= | Silent (SNP) | VAF 37/251 reads (15%) | catalogued as COSV66760396; called by muse, mutect2, varscan2
- KIF3B | c.690C>T p.L230= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs745395716, COSV65227274; called by muse, mutect2
- LRRC56 | c.501G>A p.L167= | Silent (SNP) | VAF 43/192 reads (22%) | called by muse, mutect2, varscan2
- MDGA2 | c.363C>A p.I121= | Silent (SNP) | VAF 71/367 reads (19%) | called by muse, mutect2, varscan2
- MIIP | c.171G>A p.T57= | Silent (SNP) | VAF 50/267 reads (19%) | catalogued as rs754738064; called by muse, mutect2, varscan2
- MROH5 | c.3801C>A p.P1267= | Silent (SNP) | VAF 76/188 reads (40%) | called by muse, mutect2, varscan2
- MUC5AC | c.807C>A p.L269= | Silent (SNP) | VAF 136/367 reads (37%) | called by muse, mutect2, varscan2
- NDFIP2 | c.684G>T p.G228= | Silent (SNP) | VAF 74/190 reads (39%) | called by muse, mutect2, varscan2
- NNMT | c.651C>T p.G217= | Silent (SNP) | VAF 67/452 reads (15%) | catalogued as rs139280792; called by muse, mutect2, varscan2
- NNT | c.828G>A p.V276= | Silent (SNP) | VAF 29/156 reads (19%) | called by muse, mutect2, varscan2
- NUP210 | c.3612C>T p.A1204= | Silent (SNP) | VAF 65/458 reads (14%) | catalogued as rs1022896649, COSV54414456; called by muse, mutect2, varscan2
- OR2L3 | c.655C>A p.R219= | Silent (SNP) | VAF 92/463 reads (20%) | called by muse, mutect2, varscan2
- OR2M5 | c.36C>T p.F12= | Silent (SNP) | VAF 43/184 reads (23%) | catalogued as COSV63547154; called by muse, mutect2, varscan2
- OR51I2 | c.576C>A p.I192= | Silent (SNP) | VAF 92/262 reads (35%) | catalogued as COSV58299123; called by muse, mutect2, varscan2
- OR52K2 | c.514C>A p.R172= | Silent (SNP) | VAF 75/286 reads (26%) | called by muse, mutect2, varscan2
- OR5M11 | c.219T>C p.Y73= | Silent (SNP) | VAF 51/427 reads (12%) | catalogued as rs373297071; called by muse, mutect2, varscan2
- OR8D2 | c.786C>A p.P262= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1019079301; called by muse, mutect2, varscan2
- PAF1 | c.516G>A p.R172= | Silent (SNP) | VAF 42/487 reads (9%) | called by muse, mutect2
- PCK1 | c.198C>G p.L66= | Silent (SNP) | VAF 79/274 reads (29%) | catalogued as COSV60126424; called by muse, mutect2, varscan2
- PDPR | c.1809G>A p.K603= | Silent (SNP) | VAF 27/674 reads (4%) | called by muse, mutect2
- POLQ | c.5037A>G p.Q1679= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs751387338; called by muse, mutect2, varscan2
- PREX1 | c.1683G>T p.R561= | Silent (SNP) | VAF 105/423 reads (25%) | called by muse, mutect2, varscan2
- PRKCB | c.1677C>T p.A559= | Silent (SNP) | VAF 39/242 reads (16%) | catalogued as COSV57805217; called by muse, mutect2, varscan2
- PXDNL | c.1080T>C p.L360= | Silent (SNP) | VAF 160/643 reads (25%) | called by muse, mutect2, varscan2
- RIMKLA | c.561G>T p.L187= | Silent (SNP) | VAF 57/414 reads (14%) | called by muse, mutect2, varscan2
- RYR1 | c.3945G>A p.Q1315= | Silent (SNP) | VAF 159/634 reads (25%) | called by muse, mutect2, varscan2
- SATB2 | c.453G>T p.T151= | Silent (SNP) | VAF 91/344 reads (26%) | catalogued as COSV99611124; called by muse, mutect2, varscan2
- SEMA5B | c.2571C>G p.A857= | Silent (SNP) | VAF 62/243 reads (26%) | called by muse, mutect2, varscan2
- SI | c.2964T>C p.A988= | Silent (SNP) | VAF 33/212 reads (16%) | called by muse, mutect2, varscan2
- SKP2 | c.870T>C p.L290= | Silent (SNP) | VAF 122/343 reads (36%) | called by muse, mutect2, varscan2
- SLC23A2 | c.837A>T p.L279= | Silent (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- TKTL2 | c.351G>A p.P117= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as rs369284301; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2889T>C p.S963= | Silent (SNP) | VAF 129/332 reads (39%) | called by muse, mutect2, varscan2
- TRIO | c.7062C>T p.S2354= | Silent (SNP) | VAF 28/174 reads (16%) | catalogued as rs1225639208; called by muse, mutect2, varscan2
- TTN | c.78675A>G p.P26225= (on ENST00000591111; = p.P18801= on NM_003319.4) | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- UNC13C | c.5250G>T p.L1750= | Silent (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- USH2A | c.2937G>A p.G979= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as rs1350432200, COSV56443652; called by muse, mutect2, varscan2
- WDR97 | c.3840G>A p.L1280= | Silent (SNP) | VAF 289/645 reads (45%) | catalogued as rs1371046292; called by muse, mutect2, varscan2
- ZNF771 | c.216C>T p.F72= | Silent (SNP) | VAF 13/151 reads (9%) | catalogued as rs761336496, COSV60008091; called by muse, mutect2
- ZNF804A | c.2532T>C p.P844= | Silent (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- ZNF879 | c.45G>T p.T15= | Silent (SNP) | VAF 112/326 reads (34%) | catalogued as COSV71424247; called by muse, mutect2, varscan2
- ABCC13 | n.3436C>A | RNA (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2, varscan2
- AC002511.3 | chr19:35408520 A>G | 3'Flank (SNP) | VAF 86/421 reads (20%) | called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659490 C>A | 5'Flank (SNP) | VAF 114/661 reads (17%) | called by muse, mutect2, varscan2
- ACTC1 | c.*15C>T | 3'UTR (SNP) | VAF 126/466 reads (27%) | catalogued as rs1375106413; called by muse, mutect2, varscan2
- AQP1 | c.*343C>T | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- ARHGAP33 | c.7-11C>G | Intron (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- BFAR | c.*1269C>T | 3'UTR (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- BMS1P15 | n.743C>G | RNA (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- BOD1P2 | n.360C>T | RNA (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-121-25960A>T | Intron (SNP) | VAF 116/381 reads (30%) | called by muse, mutect2, varscan2
- CES1P1 | n.751G>T | RNA (SNP) | VAF 60/293 reads (20%) | called by muse, mutect2, varscan2
- CES1P1 | n.752G>T | RNA (SNP) | VAF 59/294 reads (20%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812192 C>A | 3'Flank (SNP) | VAF 66/136 reads (49%) | catalogued as rs1240395475; called by muse, mutect2, varscan2
- DGKB | c.2126-31301C>G | Intron (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- DMPK | c.161-491A>T | Intron (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- DYNLRB1 | c.3+19C>T | Intron (SNP) | VAF 37/230 reads (16%) | called by muse, varscan2
- ESRP1 | chr8:94639116 del GGG | 5'Flank (DEL) | VAF 101/426 reads (24%) | called by mutect2, pindel, varscan2
- ETHE1 | c.712+13G>A | Intron (SNP) | VAF 48/346 reads (14%) | called by muse, varscan2
- FAM205BP | n.2013C>A | RNA (SNP) | VAF 152/552 reads (28%) | catalogued as rs1399408649; called by mutect2, varscan2
- FAM90A25P | n.513C>T | RNA (SNP) | VAF 38/220 reads (17%) | catalogued as rs1427614469; called by mutect2, varscan2
- FKBP6 | c.265+32A>G | Intron (SNP) | VAF 147/353 reads (42%) | catalogued as rs782407432; called by muse, mutect2, varscan2
- GYG1 | c.-81T>A | 5'UTR (SNP) | VAF 361/813 reads (44%) | called by muse, mutect2, varscan2
- HAL | c.1833+45G>T | Intron (SNP) | VAF 56/338 reads (17%) | called by muse, mutect2, varscan2
- HERC2P2 | n.2735C>A | RNA (SNP) | VAF 140/326 reads (43%) | called by muse, mutect2, varscan2
- IGHV1-12 | n.156C>A | RNA (SNP) | VAF 103/424 reads (24%) | called by muse, mutect2, varscan2
- IGSF5 | c.-20G>T | 5'UTR (SNP) | VAF 32/156 reads (21%) | catalogued as COSV101012149; called by muse, mutect2, varscan2
- KIDINS220 | c.3012-6068G>T | Intron (SNP) | VAF 82/245 reads (33%) | called by muse, mutect2, varscan2
- LINC01559 | n.481C>T | RNA (SNP) | VAF 136/483 reads (28%) | called by muse, mutect2, varscan2
- LINC01565 | n.1163G>A | RNA (SNP) | VAF 32/247 reads (13%) | catalogued as rs146248581; called by muse, mutect2, varscan2
- LINC02381 | n.339C>A | RNA (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- LMAN1 | c.1375-21A>G | Intron (SNP) | VAF 19/138 reads (14%) | catalogued as rs1197468501; called by muse, mutect2, varscan2
- MAP2K3 | c.50-2289C>A | Intron (SNP) | VAF 54/673 reads (8%) | called by muse, mutect2
- MGAM | c.4619-11209G>A | Intron (SNP) | VAF 16/122 reads (13%) | catalogued as rs749811910; called by muse, mutect2, varscan2
- MKS1 | c.-6G>A | 5'UTR (SNP) | VAF 154/618 reads (25%) | catalogued as rs1309362602; called by muse, mutect2, varscan2
- MMP26 | c.-145+92843G>T | Intron (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- MYADML | n.1085C>T | RNA (SNP) | VAF 70/448 reads (16%) | called by muse, mutect2, varscan2
- NLRP3 | c.-23C>A | 5'UTR (SNP) | VAF 144/555 reads (26%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.204A>G | RNA (SNP) | VAF 66/200 reads (33%) | called by muse, mutect2, varscan2
- NOL6 | c.559-18C>T | Intron (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- NOX4 | c.58-98G>A | Intron (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- PARD3B | c.2630+158A>G | Intron (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- PEX5 | c.*22G>T | 3'UTR (SNP) | VAF 225/679 reads (33%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.330+220A>T | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
- PSME3 | c.42+142C>T | Intron (SNP) | VAF 25/152 reads (16%) | catalogued as rs780446192; called by muse, mutect2, varscan2
- SHLD1 | c.-5+6364C>G | Intron (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2
- SIGLEC17P | n.1132C>T | RNA (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*2007G>C | 3'UTR (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- SLC37A2 | c.-58A>T | 5'UTR (SNP) | VAF 77/545 reads (14%) | called by muse, mutect2, varscan2
- SLC45A4 | c.-400-1901G>T | Intron (SNP) | VAF 61/328 reads (19%) | called by muse, mutect2, varscan2
- SMIM22 | n.372C>A | RNA (SNP) | VAF 76/365 reads (21%) | called by muse, mutect2, varscan2
- SPATA21 | c.34+3445C>A | Intron (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- ST7 | c.151+2911A>T | Intron (SNP) | VAF 188/600 reads (31%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+3224T>A | Intron (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- TBC1D26 | c.198+14C>T | Intron (SNP) | VAF 72/208 reads (35%) | called by muse, mutect2, varscan2
- TPI1 | c.*362G>A | 3'UTR (SNP) | VAF 79/495 reads (16%) | called by muse, mutect2, varscan2
- TRIM51BP | n.1277A>G | RNA (SNP) | VAF 26/119 reads (22%) | called by mutect2, varscan2
- TRIP12 | c.99-947G>T | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- TRPA1 | c.1644+13G>T | Intron (SNP) | VAF 61/313 reads (19%) | called by muse, mutect2, varscan2
- UBE2DNL | n.162C>G | RNA (SNP) | VAF 46/292 reads (16%) | called by muse, mutect2, varscan2
- UBE2DNL | n.163C>G | RNA (SNP) | VAF 46/291 reads (16%) | called by muse, mutect2, varscan2
- UGT2B27P | n.1199G>T | RNA (SNP) | VAF 59/206 reads (29%) | called by muse, mutect2, varscan2
- UQCRB | c.*3097C>A | 3'UTR (SNP) | VAF 66/321 reads (21%) | called by muse, mutect2, varscan2
- VPS11 | c.-680A>G | 5'UTR (SNP) | VAF 55/428 reads (13%) | called by muse, mutect2, varscan2
- WASF4P | n.1421G>T | RNA (SNP) | VAF 113/220 reads (51%) | called by muse, mutect2, varscan2
- WNT11 | c.*108G>T | 3'UTR (SNP) | VAF 49/319 reads (15%) | called by muse, mutect2, varscan2
- WNT16 | chr7:121325445 C>A | 5'Flank (SNP) | VAF 43/168 reads (26%) | catalogued as COSV55977895; called by muse, mutect2, varscan2
- ZEB2 | c.-132G>A | 5'UTR (SNP) | VAF 17/147 reads (12%) | catalogued as rs1303307148, COSV100356099; called by muse, mutect2, varscan2
- ZNF10 | c.33+421G>A | Intron (SNP) | VAF 15/35 reads (43%) | catalogued as rs1392144068; called by muse, mutect2, varscan2
